Somatic mutation profile of tumor specimen MMRF_2490_2_BM_CD138pos (aliquot MMRF_2490_2_BM_CD138pos_T1_KHS5U_L13313) from MMRF case MMRF_2490, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 81.4 years (29,723 days).
Specimen MMRF_2490_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2af0e711-a536-465b-8aec-3fb435ce7a81.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2490_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2490_1_PB_WBC_C3_KHS5U_K15207; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/222d7531-8894-43bd-9f11-12edb2076e40

The open-access MAF lists 465 somatic variants for this specimen: 172 protein-altering or splice-affecting, 44 silent, 249 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 147, 3'UTR 132, Intron 49, Silent 44, 5'UTR 26, 3'Flank 18, 5'Flank 13, RNA 11, Splice Site 7, Splice Region 6, Nonsense Mutation 5, Frame Shift Ins 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIM1 | c.72G>C p.K24N | Missense Mutation (SNP) | VAF 64/158 reads (41%) | hotspot (GDC flag); SIFT tolerated (0.48); PolyPhen benign (0.062); catalogued as COSV65164988, COSV65166078, COSV65166386; called by muse, varscan2
- ABI2 | c.1076G>A p.R359H (on ENST00000295851 / NM_001375719.1; = p.R292H on NM_005759.7 and 35 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 77/214 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.977); catalogued as COSV53693509; called by muse, mutect2, varscan2
- ADAM18 | c.630A>C p.K210N | Missense Mutation (SNP) | VAF 54/139 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1307957555; called by muse, mutect2, varscan2
- ADAMTS16 | c.1831C>T p.R611C | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs746897394; called by muse, mutect2, varscan2
- ADAMTS5 | c.1175G>A p.R392H | Missense Mutation (SNP) | VAF 46/126 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs562532375, COSV53179217, COSV53180757; called by muse, mutect2, varscan2
- ADGRD1 | c.371C>T p.A124V | Missense Mutation (SNP) | VAF 56/144 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.774); catalogued as rs749318936, COSV55446278; called by muse, mutect2, varscan2
- ALPG | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs568507509, COSV54964676; called by muse, mutect2, varscan2
- APBA3 | c.1395C>T p.R465= | Splice Region (SNP) | VAF 9/29 reads (31%) | catalogued as rs201543933; called by muse, mutect2
- ARHGAP22 | c.1997C>T p.A666V | Missense Mutation (SNP) | VAF 116/316 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs1479805702; called by muse, mutect2, varscan2
- ATRX | c.299A>G p.D100G | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.992); catalogued as rs782377443; called by muse, mutect2, varscan2
- BHLHE22 | c.518C>T p.A173V | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.013); catalogued as rs777622556; called by muse, mutect2, varscan2
- CATSPERB | c.2816A>G p.E939G | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs773625043, COSV56438626; called by muse, mutect2, varscan2
- CDH18 | c.1565G>A p.R522K | Missense Mutation (SNP) | VAF 104/288 reads (36%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.542); catalogued as rs924924323; called by muse, mutect2, varscan2
- CDK11A | c.2010C>A p.N670K (on ENST00000378633 / NM_001313896.2; = p.N667K on NM_024011.4) | Missense Mutation (SNP) | VAF 39/127 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1353376633; called by muse, mutect2
- CHD1 | c.4787+2T>C p.X1596_splice | Splice Site (SNP) | VAF 45/85 reads (53%) | catalogued as COSV52343165; called by muse, mutect2, varscan2
- CNTN6 | c.1253dup p.S419Vfs*33 | Frame Shift Ins (INS) | VAF 83/220 reads (38%) | catalogued as rs758676375; called by mutect2, varscan2
- COL1A1 | c.3197G>A p.R1066H | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs752075205, COSV99867080; called by muse, mutect2, varscan2
- COMMD2 | c.83G>A p.G28E | Missense Mutation (SNP) | VAF 107/328 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.9); catalogued as COSV71946366; called by muse, mutect2, varscan2
- COPZ2 | c.434G>A p.R145H | Missense Mutation (SNP) | VAF 95/267 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1206056623; called by muse, mutect2, varscan2
- CSMD3 | c.7749G>T p.Q2583H (on ENST00000297405 / NM_001363185.1; = p.Q2479H on NM_052900.3) | Missense Mutation (SNP) | VAF 83/313 reads (27%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.997); catalogued as COSV52210194; called by muse, mutect2, varscan2
- DLGAP1 | c.2276C>T p.T759M | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.046); catalogued as rs1027822448, COSV59784080; called by muse, mutect2, varscan2
- DMD | c.6787C>T p.R2263C | Missense Mutation (SNP) | VAF 104/260 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs200045725; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DRC7 | c.1906C>T p.R636W | Missense Mutation (SNP) | VAF 67/132 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); catalogued as rs748847770, COSV100395767, COSV61054971; called by muse, mutect2, varscan2
- DSG1 | c.679A>G p.R227G | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs148679825; called by muse, mutect2, varscan2
- DTX1 | c.162G>C p.E54D | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.131); catalogued as COSV57501098; called by muse, mutect2, varscan2
- EGR1 | c.85A>G p.M29V | Missense Mutation (SNP) | VAF 100/319 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.041); catalogued as rs768374163; called by muse, varscan2
- EIF2AK3 | c.1913G>A p.R638Q | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1288833379, COSV57546183; called by muse, mutect2, varscan2
- ENTPD6 | c.386C>T p.T129M | Missense Mutation (SNP) | VAF 98/274 reads (36%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.964); catalogued as rs545735578, COSV61751578; called by muse, mutect2, varscan2
- EPHA5 | c.1118T>G p.V373G | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56631937, COSV56681367; called by muse, mutect2, varscan2
- EVX1 | c.157G>A p.V53I | Missense Mutation (SNP) | VAF 46/121 reads (38%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV99763829; called by muse, mutect2, varscan2
- FAM155B | c.931C>T p.P311S | Missense Mutation (SNP) | VAF 89/246 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1405723573, COSV52935413; called by muse, mutect2, varscan2
- FAM8A1 | c.109C>G p.P37A | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.001); catalogued as rs971827574; called by muse, mutect2, varscan2
- GC | c.1263-1G>T p.X421_splice | Splice Site (SNP) | VAF 36/81 reads (44%) | catalogued as rs113175628; called by muse, mutect2, varscan2
- HDAC4 | c.107C>T p.T36M | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.096); catalogued as rs760140223, COSV61860013; called by muse, mutect2, varscan2
- HDLBP | c.1096G>A p.V366I | Missense Mutation (SNP) | VAF 62/168 reads (37%) | SIFT tolerated (0.43); PolyPhen benign (0.023); catalogued as rs201275944; called by muse, mutect2, varscan2
- IFT74 | c.1127A>C p.E376A | Missense Mutation (SNP) | VAF 135/253 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.94); catalogued as COSV66286341; called by muse, mutect2, varscan2
- IGHV2-70D | c.344A>G p.Y115C | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1446744170; called by muse, varscan2
- IGHV3-30 | c.70G>A p.V24M | Missense Mutation (SNP) | VAF 59/235 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.963); catalogued as rs752144607; called by muse, mutect2, varscan2
- IGKV1D-8 | c.202C>T p.L68F | Missense Mutation (SNP) | VAF 79/226 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.168); catalogued as rs780966103; called by muse, mutect2, varscan2
- IGKV2-24 | c.170A>C p.Y57S | Missense Mutation (SNP) | VAF 89/301 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.872); catalogued as rs762363282; called by muse, mutect2, varscan2
- IGLV3-1 | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 92/176 reads (52%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as rs368499668; called by muse, varscan2
- IGLV4-3 | c.196A>T p.I66L | Missense Mutation (SNP) | VAF 83/217 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs529123510; called by muse, varscan2
- INO80 | c.1012C>T p.R338C | Missense Mutation (SNP) | VAF 42/129 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62738681; called by muse, mutect2, varscan2
- JAKMIP1 | c.1358C>T p.T453M | Missense Mutation (SNP) | VAF 43/112 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs775667524; called by muse, mutect2, varscan2
- KCNJ3 | c.352G>A p.G118S | Missense Mutation (SNP) | VAF 99/228 reads (43%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV54532081; called by muse, mutect2, varscan2
- LAMA1 | c.3412G>A p.A1138T | Missense Mutation (SNP) | VAF 31/128 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs146317153; called by muse, mutect2
- LGALS1 | c.373G>A p.G125S | Missense Mutation (SNP) | VAF 107/299 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs767880851, COSV53222293; called by muse, mutect2, varscan2
- MAST4 | c.7190A>G p.E2397G (on ENST00000403625 / NM_001164664.2; = p.E2208G on NM_015183.3) | Missense Mutation (SNP) | VAF 76/218 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.687); catalogued as rs774634795; called by muse, mutect2, varscan2
- MRM2 | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 60/134 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs376300149; called by muse, mutect2, varscan2
- MTOR | c.1657C>T p.R553C | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.586); catalogued as rs1350423605, COSV63869396; called by muse, mutect2, varscan2
- NLRP5 | c.1417G>A p.V473M | Missense Mutation (SNP) | VAF 107/272 reads (39%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.557); catalogued as rs199475776; ClinVar: not provided; called by muse, mutect2, varscan2
- OLIG1 | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV100287208; called by muse, varscan2
- PCDH7 | c.1043G>T p.G348V | Missense Mutation (SNP) | VAF 115/312 reads (37%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); catalogued as COSV62343658; called by muse, mutect2, varscan2
- PCDHB16 | c.1120G>A p.D374N | Missense Mutation (SNP) | VAF 123/345 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV53360584, COSV53366059; called by muse, mutect2, varscan2
- PHF24 | c.241C>T p.R81W | Missense Mutation (SNP) | VAF 74/268 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765926916; called by muse, mutect2, varscan2
- PIM1 | c.68C>T p.T23I | Missense Mutation (SNP) | VAF 52/152 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs546301253, COSV65165568, COSV65166041; called by muse, varscan2
- RAB8A | c.205C>T p.R69W | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1470442545; called by muse, mutect2, varscan2
- RBBP6 | c.2477G>A p.R826H | Missense Mutation (SNP) | VAF 95/268 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.719); catalogued as rs367639774; called by muse, mutect2, varscan2
- RPS6KA2 | c.1193A>C p.H398P | Missense Mutation (SNP) | VAF 50/145 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV55832104; called by muse, mutect2, varscan2
- RRAS2 | c.67G>T p.G23C | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56329700, COSV56329705; called by muse, mutect2
- RTN1 | c.1916G>A p.R639H | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749408245; called by muse, mutect2, varscan2
- SHANK2 | c.3266G>A p.R1089H | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781863842, COSV53606387; called by muse, mutect2, varscan2
- SULT1B1 | c.733C>A p.P245T | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.658); catalogued as COSV60209181; called by muse, mutect2, varscan2
- SYTL1 | c.748-8G>A | Splice Region (SNP) | VAF 27/67 reads (40%) | catalogued as rs1393653476; called by muse, mutect2, varscan2
- TANC2 | c.4534G>T p.G1512* | Nonsense Mutation (SNP) | VAF 152/432 reads (35%) | catalogued as COSV101267335, COSV101267663; called by muse, mutect2, varscan2
- TCL1A | c.113C>T p.T38I | Missense Mutation (SNP) | VAF 72/218 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs201228671, COSV68085105, COSV68085114, COSV68085683; called by muse, mutect2, varscan2
- TEX15 | c.4438A>G p.T1480A (on ENST00000256246; = p.T1863A on NM_001350162.2) | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.025); catalogued as rs770682375; called by muse, mutect2, varscan2
- TGFBR1 | c.605C>T p.A202V | Missense Mutation (SNP) | VAF 69/190 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1564161322, CM165735, COSV66624829; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TMEM52B | c.10C>T p.R4* | Nonsense Mutation (SNP) | VAF 152/359 reads (42%) | catalogued as rs769702735, COSV100046501; called by muse, mutect2, varscan2
- TRAM2 | c.569G>A p.R190H | Missense Mutation (SNP) | VAF 51/142 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.916); catalogued as rs189107930; called by muse, mutect2, varscan2
- TRPC7 | c.359G>T p.R120L | Missense Mutation (SNP) | VAF 102/265 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV61454688; called by muse, mutect2, varscan2
- TTN | c.55549G>A p.G18517S (on ENST00000591111; = p.G11093S on NM_003319.4) | Missense Mutation (SNP) | VAF 93/248 reads (38%) | PolyPhen probably damaging (0.999); catalogued as rs375009570, COSV100625963; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUSC3 | c.395A>C p.D132A | Missense Mutation (SNP) | VAF 57/171 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101142547; called by muse, mutect2, varscan2
- UNC13A | c.4171G>A p.V1391I | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.179); catalogued as rs777663703; called by muse, mutect2, varscan2
- UNC80 | c.5444G>A p.R1815H | Missense Mutation (SNP) | VAF 55/141 reads (39%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.989); catalogued as rs761112873, COSV55887142; called by muse, mutect2, varscan2
- UPF2 | c.3383G>A p.R1128Q | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as rs979564728, COSV62660845; called by muse, mutect2, varscan2
- XKR7 | c.1258G>A p.V420I | Missense Mutation (SNP) | VAF 148/378 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.269); catalogued as rs538702175, COSV73813171, COSV73813507; called by muse, mutect2, varscan2
- YIF1A | c.285dup p.A96Cfs*30 | Frame Shift Ins (INS) | VAF 14/56 reads (25%) | catalogued as rs752032166; called by mutect2, varscan2
- ZBTB7A | c.118G>T p.V40L | Missense Mutation (SNP) | VAF 81/227 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.532); catalogued as COSV100475826; called by muse, mutect2, varscan2
- ZFP36L1 | c.57+1G>C p.X19_splice | Splice Site (SNP) | VAF 49/125 reads (39%) | catalogued as COSV60544075; called by muse, mutect2, varscan2
- ZMYM5 | c.1775A>G p.Y592C | Missense Mutation (SNP) | VAF 56/128 reads (44%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.993); catalogued as COSV61989061; called by muse, mutect2, varscan2
- ZNF462 | c.6352G>A p.V2118I | Missense Mutation (SNP) | VAF 70/175 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.365); catalogued as rs753969030, COSV52932673; called by muse, mutect2, varscan2
- ACTR10 | c.72T>A p.F24L | Missense Mutation (SNP) | VAF 52/125 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- ADAMTS3 | c.2425-1G>T p.X809_splice | Splice Site (SNP) | VAF 70/178 reads (39%) | called by muse, mutect2, varscan2
- ALDH7A1 | c.298A>C p.K100Q | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AMER1 | c.2710A>T p.M904L | Missense Mutation (SNP) | VAF 83/216 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD11 | c.2644A>T p.K882* | Nonsense Mutation (SNP) | VAF 93/262 reads (35%) | called by muse, mutect2, varscan2
- ANO3 | c.1287A>G p.V429= | Splice Region (SNP) | VAF 43/109 reads (39%) | called by muse, mutect2, varscan2
- ARMCX1 | c.68G>C p.C23S | Missense Mutation (SNP) | VAF 56/180 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- ASPM | c.7744dup p.I2582Nfs*7 | Frame Shift Ins (INS) | VAF 75/118 reads (64%) | called by mutect2, pindel, varscan2
- ATP2C1 | c.2299A>G p.K767E | Missense Mutation (SNP) | VAF 71/165 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- BDP1 | c.3975G>T p.E1325D | Missense Mutation (SNP) | VAF 103/304 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- BRWD3 | c.4754T>C p.M1585T | Missense Mutation (SNP) | VAF 52/134 reads (39%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); called by muse, varscan2
- CADPS2 | c.4C>A p.L2M | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- CD22 | c.2061_2064dup p.A689Sfs*48 | Frame Shift Ins (INS) | VAF 13/62 reads (21%) | called by mutect2, pindel, varscan2
- CDKL5 | c.1378C>A p.P460T | Missense Mutation (SNP) | VAF 81/218 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- CELSR3 | c.8113G>T p.A2705S | Missense Mutation (SNP) | VAF 60/162 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.305); called by muse, varscan2
- CENPH | c.733G>A p.D245N | Missense Mutation (SNP) | VAF 77/215 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- CFAP47 | c.4492C>T p.H1498Y | Missense Mutation (SNP) | VAF 93/234 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CFTR | c.979C>A p.L327I | Missense Mutation (SNP) | VAF 87/267 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.072); called by muse, varscan2
- CHRM2 | c.746C>T p.P249L | Missense Mutation (SNP) | VAF 59/156 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- CHRND | c.214A>C p.T72P | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CKMT2 | c.249C>G p.N83K | Missense Mutation (SNP) | VAF 63/196 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- CPSF1 | c.3349del p.L1117Sfs*24 | Frame Shift Del (DEL) | VAF 68/282 reads (24%) | called by mutect2, varscan2
- CRISPLD1 | c.101A>C p.K34T | Missense Mutation (SNP) | VAF 85/197 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- DAPK1 | c.3964C>T p.P1322S | Missense Mutation (SNP) | VAF 168/391 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- DCAF4L1 | c.1115T>C p.L372P | Missense Mutation (SNP) | VAF 151/411 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- DIPK2A | c.283C>T p.Q95* | Nonsense Mutation (SNP) | VAF 71/170 reads (42%) | called by muse, mutect2, varscan2
- DIS3 | c.654+1G>C p.X218_splice | Splice Site (SNP) | VAF 38/97 reads (39%) | called by muse, mutect2, varscan2
- DKK1 | c.700T>G p.F234V | Missense Mutation (SNP) | VAF 187/466 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DNAAF6 | c.-2T>G | Splice Region (SNP) | VAF 74/204 reads (36%) | called by muse, mutect2, varscan2
- DUSP2 | c.374T>A p.V125E | Missense Mutation (SNP) | VAF 52/109 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.659); called by muse, mutect2, varscan2
- EPHA7 | c.2123T>C p.M708T | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EXOSC1 | c.345G>A p.K115= | Splice Region (SNP) | VAF 100/334 reads (30%) | called by muse, mutect2, varscan2
- EYA1 | c.1225T>G p.F409V | Missense Mutation (SNP) | VAF 87/202 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.409); called by muse, mutect2, varscan2
- FAM135B | c.2415C>A p.S805R | Missense Mutation (SNP) | VAF 111/199 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAM83B | c.2641G>C p.A881P | Missense Mutation (SNP) | VAF 118/341 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GALNT16 | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 66/188 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GJD2 | c.959_960del p.Y320Cfs*8 | Frame Shift Del (DEL) | VAF 12/37 reads (32%) | called by mutect2, pindel, varscan2
- GPX1 | c.344G>T p.C115F | Missense Mutation (SNP) | VAF 93/226 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- HTATSF1 | c.855T>G p.N285K | Missense Mutation (SNP) | VAF 93/253 reads (37%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- HTATSF1 | c.1776A>C p.L592F | Missense Mutation (SNP) | VAF 95/289 reads (33%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IGHD6-25 | c.6T>G p.Y2* | Nonsense Mutation (SNP) | VAF 87/137 reads (64%) | called by muse, mutect2, varscan2
- IGHG1 | c.346G>C p.E116Q | Missense Mutation (SNP) | VAF 46/68 reads (68%) | SIFT tolerated (0.09); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- IGKV1-5 | c.25C>T p.L9F | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.108); called by muse, varscan2
- IGKV1-8 | c.227G>C p.S76T | Missense Mutation (SNP) | VAF 104/262 reads (40%) | SIFT tolerated (0.38); PolyPhen benign (0.031); called by muse, varscan2
- IGLV4-69 | c.213C>G p.N71K | Missense Mutation (SNP) | VAF 61/163 reads (37%) | SIFT tolerated (0.95); PolyPhen benign (0); called by muse, mutect2, varscan2
- ILRUN | c.314-2A>G p.X105_splice | Splice Site (SNP) | VAF 30/70 reads (43%) | called by muse, mutect2, varscan2
- IQCD | c.556A>G p.S186G | Missense Mutation (SNP) | VAF 76/210 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- JRKL | c.113G>C p.G38A | Missense Mutation (SNP) | VAF 57/127 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KLHL34 | c.821G>T p.S274I | Missense Mutation (SNP) | VAF 42/123 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- LDAH | c.653A>T p.N218I | Missense Mutation (SNP) | VAF 141/409 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- LNPK | c.1018G>A p.G340R | Missense Mutation (SNP) | VAF 75/234 reads (32%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- LYPLA2 | c.301G>T p.A101S | Missense Mutation (SNP) | VAF 72/180 reads (40%) | SIFT tolerated (0.42); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- MACROD2 | c.359T>C p.L120P | Missense Mutation (SNP) | VAF 12/286 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- METAP2 | c.518C>T p.A173V | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- MFN1 | c.1330-1G>A p.X444_splice | Splice Site (SNP) | VAF 56/189 reads (30%) | called by muse, mutect2, varscan2
- MFN2 | c.2198T>C p.L733P | Missense Mutation (SNP) | VAF 49/120 reads (41%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- NEDD4L | c.2506C>T p.P836S (on ENST00000400345 / NM_001144967.3; = p.P816S on NM_015277.6) | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- NLRP6 | c.1838A>C p.E613A | Missense Mutation (SNP) | VAF 59/144 reads (41%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- NUP210L | c.866T>A p.L289Q | Missense Mutation (SNP) | VAF 107/127 reads (84%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- OCM2 | c.196T>G p.F66V | Missense Mutation (SNP) | VAF 58/179 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- OR2T27 | c.123C>A p.S41R | Missense Mutation (SNP) | VAF 96/241 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- OR51A7 | c.34T>C p.F12L | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR5D13 | c.95T>G p.V32G | Missense Mutation (SNP) | VAF 86/227 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- PCDH10 | c.2744A>C p.D915A | Missense Mutation (SNP) | VAF 92/231 reads (40%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PCDHB16 | c.2218A>C p.S740R | Missense Mutation (SNP) | VAF 64/176 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- PDZD7 | c.1193G>A p.R398H | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- PHKA2 | c.3201G>C p.W1067C | Missense Mutation (SNP) | VAF 53/108 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PLEKHA1 | c.-20-7T>G | Splice Region (SNP) | VAF 114/352 reads (32%) | called by muse, varscan2
- PPAN-P2RY11 | c.1082A>G p.E361G | Missense Mutation (SNP) | VAF 54/157 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PRRC2C | c.6767G>A p.R2256H (on ENST00000367742; = p.R2254H on NM_015172.4) | Missense Mutation (SNP) | VAF 133/159 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RAB41 | c.265G>A p.G89S (on ENST00000374473 / NM_001363807.1; = p.G88S on NM_001032726.3) | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RFTN1 | c.746T>C p.L249P | Missense Mutation (SNP) | VAF 79/230 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- RIPOR2 | c.229G>A p.V77I | Missense Mutation (SNP) | VAF 101/262 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- RPS15 | c.92A>G p.E31G | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- SEC23IP | c.1092A>C p.E364D | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SELP | c.301_302delinsA p.W101Rfs*51 | Frame Shift Del (DEL) | VAF 56/273 reads (21%) | called by pindel, varscan2*
- SEMA5A | c.3155A>C p.N1052T | Missense Mutation (SNP) | VAF 48/136 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- SLITRK1 | c.991A>T p.R331W | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- SPTLC3 | c.323A>G p.Q108R | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- SRCAP | c.4385C>T p.P1462L | Missense Mutation (SNP) | VAF 279/738 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, varscan2
- STOX1 | c.1388G>T p.R463I | Missense Mutation (SNP) | VAF 134/332 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- TENT5D | c.303A>T p.K101N | Missense Mutation (SNP) | VAF 100/228 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TMC1 | c.2245G>A p.A749T | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.079); called by mutect2, varscan2
- TNFAIP6 | c.424C>G p.P142A | Missense Mutation (SNP) | VAF 70/185 reads (38%) | SIFT tolerated (0.51); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- VCPIP1 | c.281T>A p.V94E | Missense Mutation (SNP) | VAF 72/197 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ZBTB5 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 130/268 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- ZNF462 | c.937C>T p.P313S | Missense Mutation (SNP) | VAF 95/274 reads (35%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF532 | c.824C>A p.A275E | Missense Mutation (SNP) | VAF 68/197 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- ZNF630 | c.1178A>G p.H393R | Missense Mutation (SNP) | VAF 52/127 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- ZNF646 | c.1447C>T p.H483Y | Missense Mutation (SNP) | VAF 119/338 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ALPL | c.1353C>T p.H451= | Silent (SNP) | VAF 69/202 reads (34%) | catalogued as rs377110098; called by muse, mutect2, varscan2
- ARMC4 | c.861A>G p.K287= | Silent (SNP) | VAF 26/55 reads (47%) | catalogued as COSV53468388; called by muse, mutect2, varscan2
- C6orf226 | c.81G>T p.L27= | Silent (SNP) | VAF 41/101 reads (41%) | called by muse, mutect2, varscan2
- CARMIL1 | c.3606C>T p.G1202= | Silent (SNP) | VAF 46/119 reads (39%) | catalogued as rs764642099; called by muse, mutect2, varscan2
- COL3A1 | c.186C>T p.C62= | Silent (SNP) | VAF 136/377 reads (36%) | catalogued as rs764749176, COSV58593556; ClinVar: likely benign; called by muse, mutect2, varscan2
- DNER | c.1830T>C p.G610= | Silent (SNP) | VAF 23/106 reads (22%) | called by muse, mutect2, varscan2
- DSCAM | c.1044C>T p.Y348= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as rs778177192; called by muse, mutect2, varscan2
- DUSP2 | c.375G>A p.V125= | Silent (SNP) | VAF 36/109 reads (33%) | catalogued as rs1005029732; called by muse, mutect2, varscan2
- EGFLAM | c.2361C>T p.P787= | Silent (SNP) | VAF 68/173 reads (39%) | catalogued as COSV100380853; called by muse, mutect2, varscan2
- EPS15L1 | c.1668G>A p.E556= | Silent (SNP) | VAF 44/103 reads (43%) | called by muse, mutect2, varscan2
- GAB4 | c.105G>A p.T35= | Silent (SNP) | VAF 22/64 reads (34%) | called by muse, mutect2, varscan2
- GLUD2 | c.1221G>T p.G407= | Silent (SNP) | VAF 100/222 reads (45%) | called by muse, mutect2, varscan2
- IL1A | c.414C>T p.D138= | Silent (SNP) | VAF 58/189 reads (31%) | catalogued as rs376957964, COSV99641326; called by muse, mutect2, varscan2
- KIAA1210 | c.2937G>A p.K979= | Silent (SNP) | VAF 63/178 reads (35%) | called by muse, mutect2, varscan2
- LRP2 | c.11451C>T p.C3817= | Silent (SNP) | VAF 65/189 reads (34%) | catalogued as rs745376364, COSV55565185; called by muse, mutect2, varscan2
- LRRN4 | c.723G>A p.L241= | Silent (SNP) | VAF 47/109 reads (43%) | called by muse, mutect2, varscan2
- MEA1 | c.141G>A p.G47= | Silent (SNP) | VAF 85/220 reads (39%) | catalogued as rs771725871; called by muse, mutect2, varscan2
- MKX | c.393C>T p.T131= | Silent (SNP) | VAF 72/220 reads (33%) | catalogued as rs760522501; called by muse, mutect2, varscan2
- MUC17 | c.10935A>C p.T3645= | Silent (SNP) | VAF 105/286 reads (37%) | called by muse, mutect2, varscan2
- MUC5B | c.9024C>T p.S3008= | Silent (SNP) | VAF 82/197 reads (42%) | catalogued as COSV71591901; called by muse, mutect2, varscan2
- NPAS3 | c.1728G>A p.T576= (on ENST00000356141 / NM_001164749.2; = p.T544= on NM_022123.3) | Silent (SNP) | VAF 101/227 reads (44%) | called by muse, mutect2, varscan2
- NXPE1 | c.1143C>A p.I381= (on ENST00000424269; = p.I239= on NM_152315.5) | Silent (SNP) | VAF 64/168 reads (38%) | catalogued as rs765334619; called by muse, mutect2, varscan2
- OBSL1 | c.186G>A p.A62= | Silent (SNP) | VAF 26/48 reads (54%) | called by muse, mutect2, varscan2
- ODF4 | c.708G>A p.T236= | Silent (SNP) | VAF 87/225 reads (39%) | catalogued as rs138113934; called by muse, mutect2, varscan2
- PCDH17 | c.2454G>A p.P818= | Silent (SNP) | VAF 32/52 reads (62%) | called by muse, mutect2, varscan2
- PDE2A | c.1497G>A p.T499= | Silent (SNP) | VAF 65/143 reads (45%) | catalogued as rs899573405; called by muse, mutect2, varscan2
- PEX12 | c.300T>C p.S100= | Silent (SNP) | VAF 107/369 reads (29%) | called by muse, mutect2, varscan2
- PI15 | c.300G>A p.S100= | Silent (SNP) | VAF 90/252 reads (36%) | catalogued as rs1423685861, COSV52640862, COSV52644839; called by muse, mutect2, varscan2
- PPP1R9A | c.1839G>A p.Q613= | Silent (SNP) | VAF 52/141 reads (37%) | called by muse, mutect2, varscan2
- PRKCG | c.1425C>A p.G475= | Silent (SNP) | VAF 111/306 reads (36%) | called by muse, mutect2, varscan2
- PRRT1 | c.402G>A p.P134= | Silent (SNP) | VAF 5/26 reads (19%) | called by muse, mutect2, varscan2
- PTGER2 | c.342C>T p.F114= | Silent (SNP) | VAF 139/320 reads (43%) | catalogued as rs1397436185; called by muse, mutect2, varscan2
- RNF213 | c.15057C>T p.S5019= | Silent (SNP) | VAF 65/210 reads (31%) | catalogued as rs767371073, COSV60410534; called by muse, mutect2, varscan2
- SEC24D | c.99G>C p.S33= | Silent (SNP) | VAF 96/259 reads (37%) | called by muse, mutect2, varscan2
- SLC37A2 | c.1476G>C p.L492= | Silent (SNP) | VAF 103/239 reads (43%) | called by muse, mutect2, varscan2
- SLC39A7 | c.15G>A p.L5= | Silent (SNP) | VAF 65/172 reads (38%) | called by muse, mutect2, varscan2
- TIAM1 | c.1242C>T p.S414= | Silent (SNP) | VAF 75/178 reads (42%) | catalogued as rs765934871, COSV54557443; called by muse, mutect2, varscan2
- TMEM67 | c.2793G>A p.L931= | Silent (SNP) | VAF 24/66 reads (36%) | called by muse, mutect2, varscan2
- TPBGL | c.1023C>T p.R341= | Silent (SNP) | VAF 38/107 reads (36%) | called by muse, mutect2, varscan2
- TPRX1 | c.186C>A p.I62= | Silent (SNP) | VAF 45/106 reads (42%) | catalogued as COSV100445973; called by muse, mutect2, varscan2
- TRPC1 | c.1287G>C p.L429= (on ENST00000476941 / NM_001251845.2; = p.L395= on NM_003304.4) | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as rs1242265471; called by muse, mutect2
- UBQLN3 | c.999T>C p.F333= | Silent (SNP) | VAF 58/136 reads (43%) | catalogued as rs753601730; called by muse, mutect2, varscan2
- VWCE | c.1812G>A p.R604= | Silent (SNP) | VAF 43/98 reads (44%) | called by muse, mutect2, varscan2
- ZXDC | c.1752C>T p.L584= | Silent (SNP) | VAF 53/177 reads (30%) | catalogued as rs573894842, COSV60448854; called by muse, mutect2, varscan2
- ABI3BP | c.1064-312T>A | Intron (SNP) | VAF 8/15 reads (53%) | catalogued as rs1035283810; called by muse, mutect2, varscan2
- AC024651.2 | chr15:97874371 A>C | 5'Flank (SNP) | VAF 14/34 reads (41%) | called by mutect2, varscan2
- AC092718.9 | chr16:81148334 C>A | 5'Flank (SNP) | VAF 53/119 reads (45%) | called by muse, mutect2, varscan2
- AC099654.2 | n.1342T>C | RNA (SNP) | VAF 11/30 reads (37%) | called by muse, mutect2
- AC112695.1 | n.382T>C | RNA (SNP) | VAF 17/45 reads (38%) | called by muse, mutect2, varscan2
- ADAM20P1 | n.1319C>T | RNA (SNP) | VAF 80/186 reads (43%) | called by muse, mutect2, varscan2
- ADAMTS18 | c.-224G>A | 5'UTR (SNP) | VAF 33/99 reads (33%) | catalogued as rs1019240492; called by muse, mutect2, varscan2
- ADCY2 | c.*2479T>C | 3'UTR (SNP) | VAF 37/105 reads (35%) | called by muse, mutect2, varscan2
- ADGRF1 | c.*1873G>A | 3'UTR (SNP) | VAF 12/150 reads (8%) | called by muse, mutect2
- ADGRL4 | c.*869G>T | 3'UTR (SNP) | VAF 29/43 reads (67%) | called by muse, mutect2, varscan2
- ADNP | chr20:50890164 A>G | 3'Flank (SNP) | VAF 14/42 reads (33%) | catalogued as rs1219862412; called by muse, mutect2, varscan2
- AGAP1 | c.*1944del | 3'UTR (DEL) | VAF 32/106 reads (30%) | catalogued as rs1289136451; called by mutect2, pindel, varscan2
- AGO4 | c.*4086A>T | 3'UTR (SNP) | VAF 28/74 reads (38%) | called by muse, mutect2, varscan2
- ANKRD13B | c.422-30A>G | Intron (SNP) | VAF 60/150 reads (40%) | called by muse, mutect2, varscan2
- ANKS1B | c.3672+7031G>A | Intron (SNP) | VAF 27/69 reads (39%) | called by muse, mutect2, varscan2
- AQP7 | c.406+54A>T | Intron (SNP) | VAF 24/89 reads (27%) | called by muse, mutect2, varscan2
- AR | c.1885+8857T>C | Intron (SNP) | VAF 31/82 reads (38%) | called by muse, mutect2, varscan2
- AR | c.*5565C>A | 3'UTR (SNP) | VAF 36/90 reads (40%) | catalogued as rs1486034191; called by muse, mutect2, varscan2
- ARFGEF2 | c.*919T>C | 3'UTR (SNP) | VAF 20/52 reads (38%) | called by muse, mutect2, varscan2
- ARID5B | c.*1317G>A | 3'UTR (SNP) | VAF 25/63 reads (40%) | called by muse, mutect2, varscan2
- ART4 | c.-104del | 5'UTR (DEL) | VAF 34/96 reads (35%) | called by mutect2, varscan2
- ATP5F1E | c.*4-516G>A | Intron (SNP) | VAF 28/60 reads (47%) | called by muse, mutect2, varscan2
- B3GNTL1 | c.409-458C>T | Intron (SNP) | VAF 10/23 reads (43%) | catalogued as rs752887900; called by muse, varscan2
- B4GALT6 | chr18:31622368 A>C | 3'Flank (SNP) | VAF 30/126 reads (24%) | called by muse, mutect2, varscan2
- BAALC | chr8:103228810 T>C | 3'Flank (SNP) | VAF 73/179 reads (41%) | called by muse, mutect2, varscan2
- BCAP31 | c.602-148G>T | Intron (SNP) | VAF 4/13 reads (31%) | called by muse, mutect2
- BCL11B | c.*1868G>A | 3'UTR (SNP) | VAF 43/126 reads (34%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021517 G>C | 5'Flank (SNP) | VAF 83/191 reads (43%) | catalogued as COSV55846497, COSV55849856; called by muse, mutect2, varscan2
- BDNF | c.*254G>A | 3'UTR (SNP) | VAF 59/160 reads (37%) | called by muse, mutect2, varscan2
- BMPR1B | chr4:95156403 G>C | 3'Flank (SNP) | VAF 5/26 reads (19%) | called by muse, mutect2, varscan2
- BMT2 | c.*2448T>C | 3'UTR (SNP) | VAF 50/116 reads (43%) | called by muse, mutect2, varscan2
- C14orf132 | chr14:96088559 G>A | 3'Flank (SNP) | VAF 50/185 reads (27%) | called by muse, mutect2, varscan2
- C2orf72 | c.*376G>A | 3'UTR (SNP) | VAF 52/121 reads (43%) | called by muse, mutect2, varscan2
- C6orf201 | c.-234C>T | 5'UTR (SNP) | VAF 36/100 reads (36%) | called by muse, mutect2, varscan2
- CACHD1 | c.*171A>G | 3'UTR (SNP) | VAF 25/58 reads (43%) | called by muse, mutect2, varscan2
- CACNA2D1 | chr7:81949947 A>C | 3'Flank (SNP) | VAF 33/105 reads (31%) | called by muse, mutect2, varscan2
- CACUL1 | c.*1044A>T | 3'UTR (SNP) | VAF 45/111 reads (41%) | called by muse, mutect2, varscan2
- CALCOCO1 | c.*603dup | 3'UTR (INS) | VAF 14/72 reads (19%) | catalogued as rs889484981; called by mutect2, pindel, varscan2
- CALD1 | c.*1352T>C | 3'UTR (SNP) | VAF 31/93 reads (33%) | called by muse, mutect2, varscan2
- CALN1 | c.*5360T>C | 3'UTR (SNP) | VAF 7/23 reads (30%) | called by muse, mutect2, varscan2
- CASKIN1 | c.*1208C>T | 3'UTR (SNP) | VAF 14/46 reads (30%) | called by muse, mutect2, varscan2
- CBLIF | c.371-22A>C | Intron (SNP) | VAF 31/72 reads (43%) | called by muse, mutect2, varscan2
- CCM2 | c.746-1056G>T | Intron (SNP) | VAF 14/36 reads (39%) | called by muse, mutect2, varscan2
- CD177P1 | n.22C>A | RNA (SNP) | VAF 48/163 reads (29%) | called by muse, mutect2, varscan2
- CD27 | c.-88A>G | 5'UTR (SNP) | VAF 24/62 reads (39%) | called by muse, mutect2, varscan2
- CD7 | c.613-60G>A | Intron (SNP) | VAF 64/166 reads (39%) | called by muse, mutect2, varscan2
- CD81 | c.561+22G>A | Intron (SNP) | VAF 38/86 reads (44%) | catalogued as rs34403950, COSV55133961; called by muse, mutect2, varscan2
- CDH8 | c.*5924A>G | 3'UTR (SNP) | VAF 23/53 reads (43%) | called by muse, mutect2, varscan2
- CEP78 | c.*6798G>C | 3'UTR (SNP) | VAF 79/153 reads (52%) | called by muse, mutect2, varscan2
- CNKSR2 | c.*532A>G | 3'UTR (SNP) | VAF 15/45 reads (33%) | called by muse, mutect2, varscan2
- CNKSR2 | c.*2001T>A | 3'UTR (SNP) | VAF 30/78 reads (38%) | called by muse, mutect2, varscan2
- CNTN1 | c.1805-9225T>A | Intron (SNP) | VAF 110/261 reads (42%) | catalogued as rs929875055; called by muse, mutect2, varscan2
- COL6A1 | c.*115dup | 3'UTR (INS) | VAF 20/66 reads (30%) | catalogued as rs889031226; called by mutect2, varscan2
- COLGALT2 | c.*2916dup | 3'UTR (INS) | VAF 20/30 reads (67%) | catalogued as rs966809808; called by mutect2, varscan2
- COPE | c.444-165_444-162dup | Intron (INS) | VAF 43/112 reads (38%) | called by mutect2, pindel, varscan2
- CPS1 | c.*685G>A | 3'UTR (SNP) | VAF 19/40 reads (48%) | catalogued as rs1218134492; called by muse, mutect2, varscan2
- CRELD2 | c.1009+127G>A | Intron (SNP) | VAF 11/32 reads (34%) | catalogued as rs768664834; called by muse, mutect2, varscan2
- CUBN | c.593+596T>A | Intron (SNP) | VAF 31/108 reads (29%) | called by muse, mutect2
- CXCL1 | c.*395C>T | 3'UTR (SNP) | VAF 18/28 reads (64%) | called by muse, mutect2, varscan2
- DACH2 | c.1751-1737G>T | Intron (SNP) | VAF 18/54 reads (33%) | called by muse, varscan2
- DDX31 | chr9:132593859 G>A | 3'Flank (SNP) | VAF 57/148 reads (39%) | called by muse, mutect2, varscan2
- DGKB | c.2307+637C>A | Intron (SNP) | VAF 52/126 reads (41%) | catalogued as COSV51771915; called by muse, mutect2, varscan2
- DLX1 | c.*1169A>C | 3'UTR (SNP) | VAF 42/147 reads (29%) | called by muse, mutect2, varscan2
- DMRTA1 | c.-152C>A | 5'UTR (SNP) | VAF 76/120 reads (63%) | called by muse, mutect2, varscan2
- DOK6 | c.-15C>T | 5'UTR (SNP) | VAF 63/151 reads (42%) | called by muse, mutect2, varscan2
- DPPA4 | c.*1209C>A | 3'UTR (SNP) | VAF 46/131 reads (35%) | called by muse, mutect2, varscan2
- DPYSL3 | c.*149C>A | 3'UTR (SNP) | VAF 35/110 reads (32%) | catalogued as rs929679125; called by muse, mutect2, varscan2
- DR1 | chr1:93361750 A>G | 3'Flank (SNP) | VAF 12/48 reads (25%) | called by muse, mutect2, varscan2
- DTX1 | c.-353C>T | 5'UTR (SNP) | VAF 34/89 reads (38%) | catalogued as rs1173099979; called by muse, mutect2, varscan2
- DTX4 | c.*1627T>C | 3'UTR (SNP) | VAF 5/12 reads (42%) | called by muse, mutect2, varscan2
- EEF1A1 | c.-31+176G>A | Intron (SNP) | VAF 49/161 reads (30%) | called by muse, mutect2, varscan2
- EGR1 | c.-126G>A | 5'UTR (SNP) | VAF 7/29 reads (24%) | catalogued as COSV53520591; called by muse, mutect2, varscan2
- EMX1 | chr2:72916363 C>T | 5'Flank (SNP) | VAF 58/110 reads (53%) | called by muse, mutect2, varscan2
- EXOC4 | c.*86A>C | 3'UTR (SNP) | VAF 79/193 reads (41%) | called by muse, mutect2, varscan2
- FAM110C | c.*353T>A | 3'UTR (SNP) | VAF 20/48 reads (42%) | catalogued as rs896914654; called by muse, mutect2, varscan2
- FAM120C | c.*1699G>T | 3'UTR (SNP) | VAF 30/62 reads (48%) | called by muse, mutect2, varscan2
- FAM122B | c.-694G>T | 5'UTR (SNP) | VAF 21/59 reads (36%) | called by muse, mutect2, varscan2
- FAM161B | c.*5T>C | 3'UTR (SNP) | VAF 171/465 reads (37%) | called by muse, mutect2, varscan2
- FER | c.*4634A>G | 3'UTR (SNP) | VAF 39/58 reads (67%) | called by muse, mutect2, varscan2
- FERMT1 | c.*1472G>A | 3'UTR (SNP) | VAF 56/159 reads (35%) | catalogued as rs41282954; ClinVar: uncertain significance; called by muse, mutect2
- FO681492.1 | c.-127T>C | 5'UTR (SNP) | VAF 7/22 reads (32%) | called by muse, mutect2, varscan2
- FOXE1 | c.-337C>T | 5'UTR (SNP) | VAF 24/270 reads (9%) | called by muse, mutect2
- FUT9 | c.*1150C>T | 3'UTR (SNP) | VAF 36/125 reads (29%) | called by muse, mutect2, varscan2
- GABBR1 | c.*645C>T | 3'UTR (SNP) | VAF 28/70 reads (40%) | catalogued as rs550602125; called by muse, mutect2, varscan2
- GABBR2 | c.*2308C>A | 3'UTR (SNP) | VAF 9/95 reads (9%) | called by muse, mutect2
- GDI1 | c.820-64C>T | Intron (SNP) | VAF 20/49 reads (41%) | catalogued as rs782480279; called by muse, mutect2, varscan2
- GNG12 | c.*589del | 3'UTR (DEL) | VAF 27/63 reads (43%) | called by mutect2, pindel, varscan2
- GNG5P2 | n.31A>G | RNA (SNP) | VAF 82/249 reads (33%) | called by muse, mutect2, varscan2
- GOLGA8B | c.*303C>A | 3'UTR (SNP) | VAF 37/100 reads (37%) | called by muse, mutect2, varscan2
- GPAT4 | c.*1173T>A | 3'UTR (SNP) | VAF 41/102 reads (40%) | called by muse, mutect2, varscan2
- GPC6 | c.-93G>A | 5'UTR (SNP) | VAF 38/88 reads (43%) | called by muse, mutect2, varscan2
- GPR3 | c.*773C>T | 3'UTR (SNP) | VAF 50/139 reads (36%) | catalogued as COSV64994807; called by muse, mutect2, varscan2
- GRIA2 | c.*3+73A>C | Intron (SNP) | VAF 40/106 reads (38%) | called by muse, mutect2, varscan2
- GSKIP | c.*1291del | 3'UTR (DEL) | VAF 34/113 reads (30%) | called by mutect2, pindel, varscan2
- HCN4 | c.-598C>T | 5'UTR (SNP) | VAF 7/21 reads (33%) | catalogued as rs1031301334; called by muse, mutect2, varscan2
- HEATR1 | c.*1680G>T | 3'UTR (SNP) | VAF 76/93 reads (82%) | called by muse, mutect2, varscan2
- HEATR4 | c.*63T>A | 3'UTR (SNP) | VAF 134/363 reads (37%) | called by muse, mutect2, varscan2
- HSP90AA4P | n.910T>C | RNA (SNP) | VAF 27/82 reads (33%) | called by muse, mutect2, varscan2
- HSPA12A | c.*2106C>T | 3'UTR (SNP) | VAF 48/128 reads (38%) | catalogued as rs1361534470, COSV100979901; called by muse, mutect2, varscan2
- IDS | c.1007-149T>C | Intron (SNP) | VAF 110/344 reads (32%) | called by muse, mutect2, varscan2
- IGLL5 | c.-8G>A | 5'UTR (SNP) | VAF 46/117 reads (39%) | catalogued as rs564804719; called by muse, mutect2, varscan2
- ING1 | chr13:110713258 G>A | 5'Flank (SNP) | VAF 48/142 reads (34%) | called by muse, mutect2, varscan2
- IPMK | c.*3514T>C | 3'UTR (SNP) | VAF 178/485 reads (37%) | catalogued as rs967443505; called by muse, mutect2, varscan2
- IRAG1 | c.*548dup | 3'UTR (INS) | VAF 17/59 reads (29%) | called by mutect2, pindel, varscan2
- IRX2 | c.*718A>C | 3'UTR (SNP) | VAF 26/62 reads (42%) | called by muse, mutect2, varscan2
- KCNC2 | c.*956T>G | 3'UTR (SNP) | VAF 81/170 reads (48%) | called by muse, mutect2, varscan2
- KCTD3 | c.-94C>T | 5'UTR (SNP) | VAF 15/18 reads (83%) | called by muse, mutect2, varscan2
- KCTD9 | c.*1149A>G | 3'UTR (SNP) | VAF 124/346 reads (36%) | catalogued as rs554769524; called by muse, mutect2, varscan2
- KIAA1210 | c.*371T>C | 3'UTR (SNP) | VAF 10/18 reads (56%) | called by muse, mutect2, varscan2
- KIFC2 | chr8:144474136 T>C | 3'Flank (SNP) | VAF 33/107 reads (31%) | called by muse, mutect2, varscan2
- KLC1 | c.1650+6490G>A | Intron (SNP) | VAF 32/91 reads (35%) | catalogued as rs1408143861; called by muse, mutect2, varscan2
- KMT2A | c.432+773A>G | Intron (SNP) | VAF 16/41 reads (39%) | catalogued as rs554229477; called by muse, mutect2, varscan2
- KRTAP4-3 | c.*88T>C | 3'UTR (SNP) | VAF 111/310 reads (36%) | called by muse, mutect2, varscan2
- LAMP2 | c.1093+4735G>C | Intron (SNP) | VAF 32/87 reads (37%) | called by muse, mutect2, varscan2
- LIN28B | c.*1682T>C | 3'UTR (SNP) | VAF 26/79 reads (33%) | called by muse, mutect2, varscan2
- LINC01537 | n.82A>G | RNA (SNP) | VAF 50/149 reads (34%) | catalogued as rs1262376388; called by muse, mutect2, varscan2
- LMO7DN | n.344C>T | RNA (SNP) | VAF 14/25 reads (56%) | catalogued as rs1401419745; called by muse, mutect2, varscan2
- LRATD1 | c.*1479C>A | 3'UTR (SNP) | VAF 39/100 reads (39%) | catalogued as rs1457011851; called by muse, mutect2, varscan2
- LRATD1 | c.*2926G>A | 3'UTR (SNP) | VAF 36/76 reads (47%) | catalogued as rs577736519; called by muse, mutect2, varscan2
- LTB | c.208+12C>T | Intron (SNP) | VAF 121/363 reads (33%) | catalogued as rs373114079; called by muse, mutect2, varscan2
- LTB | c.163-149C>T | Intron (SNP) | VAF 97/266 reads (36%) | catalogued as rs149833445, COSV53000289, COSV53002609; called by muse, mutect2, varscan2
- LUZP2 | c.*1264G>A | 3'UTR (SNP) | VAF 52/110 reads (47%) | called by muse, mutect2, varscan2
- MAGEC3 | c.910-591G>T | Intron (SNP) | VAF 48/147 reads (33%) | catalogued as rs959456925; called by muse, mutect2, varscan2
- MAGEC3 | c.910-590G>A | Intron (SNP) | VAF 46/148 reads (31%) | called by muse, mutect2, varscan2
- MAGI3 | c.*263G>A | 3'UTR (SNP) | VAF 33/81 reads (41%) | catalogued as rs567560945; called by muse, mutect2, varscan2
- MAP1A | c.-136C>T | 5'UTR (SNP) | VAF 93/246 reads (38%) | called by muse, mutect2, varscan2
- MAP2 | c.*1158T>A | 3'UTR (SNP) | VAF 39/100 reads (39%) | called by muse, mutect2, varscan2
- MAP2K1 | c.*825A>C | 3'UTR (SNP) | VAF 34/119 reads (29%) | called by muse, mutect2, varscan2
- MAP4K5 | c.*995T>C | 3'UTR (SNP) | VAF 61/148 reads (41%) | called by muse, mutect2, varscan2
- MAPK13 | c.*587G>A | 3'UTR (SNP) | VAF 31/59 reads (53%) | called by muse, mutect2, varscan2
- MAPK6 | c.-129C>T | 5'UTR (SNP) | VAF 80/217 reads (37%) | called by muse, mutect2, varscan2
- MASP1 | c.1303+5258T>C | Intron (SNP) | VAF 112/328 reads (34%) | called by muse, mutect2, varscan2
- MAST4 | c.*733T>C | 3'UTR (SNP) | VAF 50/103 reads (49%) | called by muse, mutect2, varscan2
- MCTP2 | c.970-1474A>T | Intron (SNP) | VAF 11/94 reads (12%) | called by muse, mutect2, varscan2
- MDGA1 | c.*2606del | 3'UTR (DEL) | VAF 25/278 reads (9%) | called by mutect2, pindel
- MEMO1 | c.*98T>A | 3'UTR (SNP) | VAF 160/437 reads (37%) | called by muse, mutect2, varscan2
- MICOS10 | c.64+11437_64+11438del | Intron (DEL) | VAF 85/259 reads (33%) | called by mutect2, pindel, varscan2
- MIDEAS | c.*3909C>T | 3'UTR (SNP) | VAF 26/83 reads (31%) | called by muse, mutect2, varscan2
- MINDY4 | c.*9T>A | 3'UTR (SNP) | VAF 113/313 reads (36%) | called by muse, mutect2, varscan2
- MOB3B | c.*3092T>C | 3'UTR (SNP) | VAF 52/113 reads (46%) | called by muse, mutect2, varscan2
- MYO1E | c.-301G>T | 5'UTR (SNP) | VAF 111/286 reads (39%) | called by muse, varscan2
- NAGK | c.580-73G>A | Intron (SNP) | VAF 91/224 reads (41%) | catalogued as rs561688594; called by muse, mutect2, varscan2
- NAPEPLD | c.*1851dup | 3'UTR (INS) | VAF 34/98 reads (35%) | called by mutect2, varscan2
- NCAM2 | c.*2264G>T | 3'UTR (SNP) | VAF 10/28 reads (36%) | called by muse, mutect2, varscan2
- NDUFS1 | c.*2144G>A | 3'UTR (SNP) | VAF 31/84 reads (37%) | called by muse, mutect2, varscan2
- NECTIN3-AS1 | n.530C>A | RNA (SNP) | VAF 8/27 reads (30%) | called by muse, mutect2, varscan2
- NEK10 | c.3010+105C>T | Intron (SNP) | VAF 35/95 reads (37%) | called by muse, mutect2, varscan2
- NFYA | c.*984G>A | 3'UTR (SNP) | VAF 47/138 reads (34%) | called by muse, mutect2, varscan2
- NIPSNAP3A | c.*737C>A | 3'UTR (SNP) | VAF 42/104 reads (40%) | called by muse, mutect2, varscan2
- NKAIN3 | c.*53G>A | 3'UTR (SNP) | VAF 120/309 reads (39%) | called by muse, mutect2, varscan2
- NR0B1 | c.*240A>C | 3'UTR (SNP) | VAF 38/95 reads (40%) | called by muse, mutect2, varscan2
- NRXN1 | c.*111G>A | 3'UTR (SNP) | VAF 19/71 reads (27%) | catalogued as rs1558505772; called by muse, mutect2, varscan2
- NUFIP2 | c.*91G>T | 3'UTR (SNP) | VAF 55/133 reads (41%) | called by muse, mutect2, varscan2
- NUP62CL | c.*285T>C | 3'UTR (SNP) | VAF 21/61 reads (34%) | called by mutect2, varscan2
- NUS1 | c.*3575C>T | 3'UTR (SNP) | VAF 18/47 reads (38%) | called by muse, varscan2
- OR12D2 | c.*129dup | 3'UTR (INS) | VAF 30/81 reads (37%) | catalogued as rs535949013; called by mutect2, varscan2
- OR2T2 | chr1:248441302 C>A | 5'Flank (SNP) | VAF 76/152 reads (50%) | called by muse, mutect2, varscan2
- OSBPL5 | c.*204G>A | 3'UTR (SNP) | VAF 12/33 reads (36%) | called by muse, mutect2, varscan2
- P2RX4 | c.*253G>A | 3'UTR (SNP) | VAF 30/88 reads (34%) | called by muse, mutect2, varscan2
- PAPOLA | c.2005-9T>A | Intron (SNP) | VAF 37/91 reads (41%) | catalogued as rs201275170, COSV53478542, COSV53478897; called by muse, varscan2
- PCDH11X | c.-801T>G | 5'UTR (SNP) | VAF 99/229 reads (43%) | called by muse, mutect2, varscan2
- PCDH19 | c.-366G>A | 5'UTR (SNP) | VAF 30/94 reads (32%) | called by muse, mutect2, varscan2
- PDE3B | c.-129C>T | 5'UTR (SNP) | VAF 14/37 reads (38%) | called by muse, mutect2, varscan2
- PDE7B | c.*3202A>G | 3'UTR (SNP) | VAF 90/215 reads (42%) | called by muse, mutect2, varscan2
- PDIA3 | c.*494A>G | 3'UTR (SNP) | VAF 20/46 reads (43%) | called by muse, mutect2, varscan2
- PEF1 | c.*511C>T | 3'UTR (SNP) | VAF 38/109 reads (35%) | catalogued as rs957261797; called by muse, mutect2, varscan2
- PFAS | c.3706+26G>A | Intron (SNP) | VAF 89/216 reads (41%) | called by muse, mutect2, varscan2
- PGK1 | c.*949T>G | 3'UTR (SNP) | VAF 31/83 reads (37%) | called by muse, mutect2, varscan2
- PHC3 | c.378+1331del | Intron (DEL) | VAF 10/84 reads (12%) | catalogued as rs200687062; called by pindel, varscan2
- PHKA2 | c.*743A>G | 3'UTR (SNP) | VAF 26/72 reads (36%) | called by mutect2, varscan2
- PIP4K2B | c.*3163C>T | 3'UTR (SNP) | VAF 52/131 reads (40%) | catalogued as rs1376412453; called by muse, mutect2, varscan2
- PLXDC2 | c.-396G>T | 5'UTR (SNP) | VAF 60/164 reads (37%) | called by muse, mutect2, varscan2
- PPIF | c.*922T>C | 3'UTR (SNP) | VAF 94/232 reads (41%) | called by muse, mutect2, varscan2
- PREX2 | c.*3508G>T | 3'UTR (SNP) | VAF 30/76 reads (39%) | called by muse, mutect2, varscan2
- PREX2 | c.*3877T>G | 3'UTR (SNP) | VAF 34/101 reads (34%) | called by muse, mutect2, varscan2
- PRKAR2B | c.*813A>T | 3'UTR (SNP) | VAF 13/38 reads (34%) | catalogued as rs968670860; called by muse, mutect2, varscan2
- PRPF40A | c.*428dup | 3'UTR (INS) | VAF 26/93 reads (28%) | called by mutect2, pindel, varscan2
- PTPRJ | c.1615+1657del | Intron (DEL) | VAF 8/22 reads (36%) | catalogued as rs982073000; called by mutect2, varscan2
- PUS10 | c.127-1208G>A | Intron (SNP) | VAF 37/84 reads (44%) | called by muse, mutect2, varscan2
- PXYLP1 | c.*948C>T | 3'UTR (SNP) | VAF 41/116 reads (35%) | called by muse, mutect2, varscan2
- RAB39B | c.*2352T>A | 3'UTR (SNP) | VAF 22/69 reads (32%) | called by muse, mutect2, varscan2
- RABGEF1 | chr7:66811338 G>A | 3'Flank (SNP) | VAF 32/83 reads (39%) | catalogued as rs1448950553; called by muse, mutect2, varscan2
- RBM3 | chrX:48574501 G>A | 5'Flank (SNP) | VAF 45/97 reads (46%) | catalogued as rs984394838; called by muse, mutect2, varscan2
- RECQL5 | c.1718+24G>A | Intron (SNP) | VAF 25/68 reads (37%) | called by muse, mutect2, varscan2
- RN7SL860P | chr19:22603284 C>G | 3'Flank (SNP) | VAF 28/108 reads (26%) | called by muse, mutect2, varscan2
- RNF212 | c.*1352del | 3'UTR (DEL) | VAF 58/152 reads (38%) | catalogued as rs567247929; called by mutect2, varscan2
- RNF31 | c.2997-72G>T | Intron (SNP) | VAF 50/117 reads (43%) | called by muse, mutect2, varscan2
- RPL37 | c.*6818C>T | 3'UTR (SNP) | VAF 65/173 reads (38%) | called by muse, mutect2, varscan2
- RTF1 | c.*1673G>A | 3'UTR (SNP) | VAF 33/95 reads (35%) | called by muse, mutect2, varscan2
- S1PR3 | chr9:88990868 G>A | 5'Flank (SNP) | VAF 9/41 reads (22%) | called by muse, mutect2
- SCUBE3 | c.*3187G>A | 3'UTR (SNP) | VAF 25/63 reads (40%) | called by muse, mutect2, varscan2
- SEL1L3 | chr4:25863560 G>A | 5'Flank (SNP) | VAF 80/196 reads (41%) | catalogued as COSV53538382; called by muse, varscan2
- SELENON | chr1:25818265 C>T | 3'Flank (SNP) | VAF 17/40 reads (43%) | called by muse, mutect2, varscan2
- SEMA3E | c.*2644G>A | 3'UTR (SNP) | VAF 35/118 reads (30%) | called by muse, mutect2, varscan2
- SEMA6D | c.*1516A>C | 3'UTR (SNP) | VAF 31/86 reads (36%) | called by muse, mutect2, varscan2
- SEPTIN6 | chrX:119617397 T>A | 3'Flank (SNP) | VAF 49/117 reads (42%) | called by muse, mutect2, varscan2
- SFXN1 | c.*1770T>C | 3'UTR (SNP) | VAF 87/150 reads (58%) | called by muse, mutect2, varscan2
- SH3KBP1 | c.726+12913G>T | Intron (SNP) | VAF 143/466 reads (31%) | called by muse, mutect2, varscan2
- SHROOM4 | c.*997+50C>G | Intron (SNP) | VAF 25/63 reads (40%) | called by muse, mutect2, varscan2
- SLC19A1 | c.*1406A>C | 3'UTR (SNP) | VAF 28/126 reads (22%) | called by muse, mutect2
- SLC39A8 | c.*504G>A | 3'UTR (SNP) | VAF 18/47 reads (38%) | called by muse, mutect2, varscan2
- SLCO5A1 | c.-193G>A | 5'UTR (SNP) | VAF 74/155 reads (48%) | called by muse, mutect2, varscan2
- SLIRP | chr14:77720528 C>T | 3'Flank (SNP) | VAF 78/229 reads (34%) | catalogued as rs1483661295; called by muse, mutect2, varscan2
- SLITRK1 | c.-639C>T | 5'UTR (SNP) | VAF 51/131 reads (39%) | called by muse, mutect2, varscan2
- SOX11 | c.*2304A>G | 3'UTR (SNP) | VAF 11/26 reads (42%) | called by muse, mutect2, varscan2
- SPAG16 | c.536+292C>T | Intron (SNP) | VAF 34/98 reads (35%) | called by muse, mutect2
- SPATA6 | c.*2151A>G | 3'UTR (SNP) | VAF 33/61 reads (54%) | called by muse, mutect2, varscan2
- SPRY3 | c.*5817T>G | 3'UTR (SNP) | VAF 111/286 reads (39%) | called by muse, mutect2, varscan2
- SQLE | c.291+328C>A | Intron (SNP) | VAF 285/520 reads (55%) | catalogued as rs1211580087; called by muse, varscan2
- SSPOP | n.4884G>A | RNA (SNP) | VAF 5/11 reads (45%) | called by muse, mutect2, varscan2
- ST6GALNAC2 | chr17:76563459 C>A | 3'Flank (SNP) | VAF 28/544 reads (5%) | called by muse, mutect2
- STAU2 | chr8:73747467 G>A | 5'Flank (SNP) | VAF 65/161 reads (40%) | called by muse, mutect2, varscan2
- STEAP2 | c.*4619C>A | 3'UTR (SNP) | VAF 32/75 reads (43%) | called by muse, mutect2, varscan2
- STK17B | c.*1297A>G | 3'UTR (SNP) | VAF 69/182 reads (38%) | catalogued as rs530649451; called by muse, mutect2, varscan2
- TBC1D5 | c.*787A>C | 3'UTR (SNP) | VAF 31/85 reads (36%) | called by muse, mutect2, varscan2
- TCP11X3P | n.1128T>C | RNA (SNP) | VAF 66/180 reads (37%) | called by muse, mutect2, varscan2
- TECRL | chr4:64276710 C>A | 3'Flank (SNP) | VAF 22/77 reads (29%) | catalogued as rs916773145; called by muse, mutect2, varscan2
- TEKT1 | c.*889A>C | 3'UTR (SNP) | VAF 60/127 reads (47%) | called by muse, mutect2, varscan2
- TENM2 | chr5:168263703 G>C | 3'Flank (SNP) | VAF 32/80 reads (40%) | called by muse, mutect2, varscan2
- TENT5A | c.*1419del | 3'UTR (DEL) | VAF 26/78 reads (33%) | catalogued as rs961290506; called by mutect2, varscan2
- TFPI2 | c.*934G>A | 3'UTR (SNP) | VAF 14/49 reads (29%) | called by muse, mutect2, varscan2
- TIRAP | c.*901C>T | 3'UTR (SNP) | VAF 274/737 reads (37%) | called by muse, varscan2
- TMC2 | c.83-10G>A | Intron (SNP) | VAF 17/51 reads (33%) | catalogued as rs1329804673; called by muse, mutect2, varscan2
- TMCC1 | c.*1124G>A | 3'UTR (SNP) | VAF 64/189 reads (34%) | called by muse, mutect2, varscan2
- TMEM116 | c.-301G>C | 5'UTR (SNP) | VAF 74/216 reads (34%) | called by muse, mutect2, varscan2
- TMEM164 | c.*2665G>A | 3'UTR (SNP) | VAF 127/374 reads (34%) | catalogued as rs1350596148; called by muse, mutect2, varscan2
- TMEM182 | chr2:102762018 G>A | 5'Flank (SNP) | VAF 17/53 reads (32%) | catalogued as rs959555859; called by muse, mutect2, varscan2
- TMEM30A | c.*1497T>A | 3'UTR (SNP) | VAF 25/87 reads (29%) | catalogued as rs559748543, COSV57874943; called by muse, mutect2, varscan2
- TMEM80 | c.460+347A>G | Intron (SNP) | VAF 119/307 reads (39%) | catalogued as rs1380396734; called by muse, mutect2, varscan2
- TMSB4X | chrX:12975473 A>G | 5'Flank (SNP) | VAF 101/259 reads (39%) | called by muse, mutect2, varscan2
- TMSB4X | c.*244G>C | 3'UTR (SNP) | VAF 60/150 reads (40%) | called by muse, mutect2, varscan2
- TMX4 | c.*1926C>T | 3'UTR (SNP) | VAF 35/122 reads (29%) | called by muse, mutect2, varscan2
- TNRC6A | c.*1190T>A | 3'UTR (SNP) | VAF 51/125 reads (41%) | called by muse, mutect2, varscan2
- TP63 | c.*1594T>G | 3'UTR (SNP) | VAF 30/82 reads (37%) | called by muse, mutect2, varscan2
- TYRO3 | c.*192C>T | 3'UTR (SNP) | VAF 20/66 reads (30%) | catalogued as rs1232182418; called by muse, mutect2, varscan2
- UNC79 | chr14:93430853 T>C | 5'Flank (SNP) | VAF 11/36 reads (31%) | called by muse, mutect2, varscan2
- VGF | c.*210G>A | 3'UTR (SNP) | VAF 51/130 reads (39%) | catalogued as rs868168937; called by muse, mutect2, varscan2
- VWA5A | c.*97C>T | 3'UTR (SNP) | VAF 68/171 reads (40%) | called by muse, mutect2
- YES1 | c.*156dup | 3'UTR (INS) | VAF 48/120 reads (40%) | catalogued as rs1319799918; called by mutect2, varscan2
- ZDHHC14 | c.-829C>T | 5'UTR (SNP) | VAF 20/56 reads (36%) | called by muse, varscan2
- ZFHX4 | c.*2243A>G | 3'UTR (SNP) | VAF 22/70 reads (31%) | catalogued as rs72659527, COSV50983696; called by mutect2, varscan2
- ZMYND8 | c.*319A>C | 3'UTR (SNP) | VAF 18/40 reads (45%) | called by mutect2, varscan2
- ZNF420 | c.*1059dup | 3'UTR (INS) | VAF 102/262 reads (39%) | called by mutect2, varscan2
- ZNF606 | c.88+173G>A | Intron (SNP) | VAF 26/60 reads (43%) | catalogued as rs750722060; called by muse, mutect2, varscan2
- ZNF655 | c.136+1625T>C | Intron (SNP) | VAF 16/32 reads (50%) | called by muse, mutect2
- ZNF687 | c.*238T>G | 3'UTR (SNP) | VAF 135/166 reads (81%) | called by muse, mutect2, varscan2
- ZNF782 | c.*1153G>A | 3'UTR (SNP) | VAF 8/60 reads (13%) | called by muse, mutect2, varscan2
- ZNF813 | c.*2284G>A | 3'UTR (SNP) | VAF 8/22 reads (36%) | catalogued as rs936268447; called by muse, mutect2, varscan2
- ZNF880 | chr19:52390266 G>A | 3'Flank (SNP) | VAF 22/60 reads (37%) | catalogued as rs775422786; called by muse, mutect2, varscan2
